CCDI case PBBYMJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/0cdd269b-b4dc-46a1-b4d1-7056a4c4e93f

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.2 years (5,559 days).

Biospecimens (3 samples)
- Sample 0DR9BM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR9C1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DR9CN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
